Somatic mutation profile of tumor specimen C3L-05894-54 (aliquot CPT0300520002) from CPTAC case C3L-05894, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 57.7 years (21,090 days).
Specimen C3L-05894-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11a67582-1653-4b2f-86f1-644be13f8ebb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05894-50 (Buccal Cell Normal), aliquot CPT0300490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/366d9d9f-862d-4b54-ac43-60ac07c3f18a

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, 5'Flank 1, Intron 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 101/231 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 68/192 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 87/183 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- FETUB | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149523201, COSV54004743; called by muse, mutect2, varscan2
- IRS1 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs13306470; called by muse, mutect2, varscan2
- RGPD3 | c.275C>A p.T92K | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1286185527; called by muse, mutect2, varscan2
- UGT3A2 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); catalogued as rs767595305, COSV56931184; called by muse, mutect2, varscan2
- VAV2 | c.925C>T p.Q309* (on ENST00000371850 / NM_001134398.2; = p.Q304* on NM_003371.4) | Nonsense Mutation (SNP) | VAF 60/131 reads (46%) | catalogued as COSV64081050; called by muse, mutect2, varscan2
- ARHGEF38 | c.11A>C p.K4T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- DDX42 | c.2050G>T p.A684S | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DNAH17 | c.12870G>A p.M4290I | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NR1H4 | c.1128A>G p.I376M (on ENST00000551379 / NM_001206993.2; = p.I362M on NM_005123.4) | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); called by muse, mutect2
- PCDH7 | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- CSMD2 | c.6528C>A p.P2176= | Silent (SNP) | VAF 45/107 reads (42%) | called by mutect2, varscan2
- GABRA3 | c.228C>T p.D76= | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as rs201122592, COSV64798706; called by muse, mutect2, varscan2
- ITGAL | c.1968C>A p.I656= | Silent (SNP) | VAF 42/72 reads (58%) | catalogued as COSV63323594; called by muse, mutect2, varscan2
- ZXDA | c.447G>A p.P149= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as rs776996690; called by muse, varscan2
- ZXDB | c.459G>A p.P153= | Silent (SNP) | VAF 62/228 reads (27%) | called by muse, varscan2
- CXADRP2 | n.436G>A | RNA (SNP) | VAF 32/143 reads (22%) | catalogued as rs199887961; called by mutect2, varscan2
- GPNMB | c.541+17C>T | Intron (SNP) | VAF 138/319 reads (43%) | called by muse, mutect2, varscan2
- H3P12 | chr3:109410188 G>A | 5'Flank (SNP) | VAF 109/244 reads (45%) | catalogued as rs906202336; called by muse, mutect2, varscan2
